FM case AD17020 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/690be982-5eb9-46c6-91dd-8eb2d74068ae

Female, 82.1 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
